Gene-level copy-number profile of tumor specimen TCGA-BR-4191-01A from TCGA case TCGA-BR-4191, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G2; Age at diagnosis: 72.7 years (26,562 days).
Specimen TCGA-BR-4191-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.37d0522b-3b01-43a9-b855-d4a27f5e71db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4191-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aef70955-8fed-4ef5-b5c9-183140e348f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 10,876; copy number 2: 36,390; copy number 3: 9,637; copy number 4: 2,182; copy number 5: 609; copy number 6: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4191-01A-02D-1130-01): tumor purity 0.51, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:169,912,705–174,001,488, 49 genes (within-gene range 0–1): AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1, HSP90AA6P, LINC02382, AC097486.1, RNU6ATAC13P, AC034159.2, LINC02431, AC034159.1, AC092639.1, MIR6082, LINC02504, AC074254.2, LINC02174, AC074254.1, GALNTL6, AC108064.1, AC105285.1, RN7SL253P, GALNT7, MIR548T, AC097534.1, HMGB2, SAP30-DT, SAP30, SCRG1, AC093849.4, RPL5P11, AC093849.3, RNU6-1096P, AC093849.1, AC093849.2, HAND2, HAND2-AS1, MORF4, RANP6, LINC02269, AC106895.1, AC106895.2.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr10:87,659,613–87,971,930, 7 genes (within-gene range 0–1): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 612 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:157,543,246–172,401,669, 191 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:193,842,560–198,222,513, 161 genes, copy number 5 (broad region; genes not listed).
- chr20:49,293,394–55,075,140, 98 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:55,420,336–55,427,197, 1 gene, copy number 6: LINC01441.
- chr20:59,577,509–59,847,711, 1 gene, copy number 5 (within-gene range 4–5): PHACTR3.
- chr20:59,852,667–64,313,132, 160 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
